Surgical pathology report (de-identified scan), TCGA case TCGA-N7-A4Y0, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Washington University, specimen TCGA-N7-A4Y0-01A (Primary Tumor).

[page 1 of 4]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

ICD-0-3
Carcinosarcoma, Mixed Mullerian
Tumor, malignant 8950/3
Site: Corpus Uteri, Endometrium
C54.1
Jed 5/28/13

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Address: [REDACTED]
Gender: F
DOB: [REDACTED]
Physician(s): [REDACTED]
Service: Gynecology
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]
Accession
Taken:
Received:
Reported:

Other Related Clinical Data:

DIAGNOSIS:

- UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- MALIGNANT MIXED MULLERIAN TUMOR (MMMT) WITH HETEROLOGOUS DIFFERENTIATION
- MMT EXTENSIVELY INVOLVES THE LOWER UTERINE SEGMENT
- SEE SYNOPSIS
- UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- MMT BY DIRECT EXTENSION, INVADING TO A DEPTH OF 13 MM WHERE MYOMETRIAL THICKNESS IS 18 MM
- LYMPHOVASCULAR INVASION BY MMT IS IDENTIFIED
- UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- CHRONIC INFLAMMATION
- OVARY, RIGHT, SALPINGO-OOPHORECTOMY
- NO EVIDENCE OF MALIGNANCY
- OVARY, LEFT, SALPINGO-OOPHORECTOMY
- NO EVIDENCE OF MALIGNANCY
- FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY
- NO EVIDENCE OF MALIGNANCY
- LYMPH NODES, RIGHT PELVIC, EXCISION
- METASTATIC MALIGNANT MIXED MULLERIAN TUMOR IN TWO OF SIX LYMPH NODES (2/6), WITH EXTRACAPSULAR EXTENSION
- LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION
- NO EVIDENCE OF MALIGNANCY IN FOUR NODES
- LYMPH NODES, LEFT OBTURATOR, EXCISION
- NO EVIDENCE OF MALIGNANCY IN THREE LYMPH NODES
- LYMPH NODES, RIGHT PERI-AORTIC, EXCISION
- NO EVIDENCE OF MALIGNANCY IN FIVE LYMPH NODES
- LYMPH NODES, LEFT PERI-AORTIC, EXCISION
- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES
- SKIN, ABDOMINAL, EXCISION
- DERMAL SCAR

By this signature, I attest that the above diagnosis is based upon my personal

[page 2 of 4]
Patient Name: [REDACTED]

examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

"Called to OR to open 'uterus, tube and rt. ovary,' consists of a 9.3 cm (fundus-external os) x 5.7 cm (cornu-cornu) x 5.4 cm (anterior to posterior) uterus with attached cervix, right fallopian tube and presumed atrophic right ovary, weighing 164 grams in aggregate. Opened in OR to show large polypoid mass filling uterine cavity. Shown to surgeon. Tissue taken for [REDACTED] and tumor bank. Rest for permanent," by

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] year old woman with malignant mixed mullerian tumor with heterologous elements of endometrium. Operative procedure:

Examination under anesthesia, total abdominal hysterectomy, bilateral salpingo-oophorectomy and lymph node dissection.

Specimen(s) Received:

- A: UTERUS, FALLOPIAN TUBE, AND RIGHT OVARY
- B: LYMPH NODES, RIGHT PELVIC
- C: LYMPH NODES, LEFT EXTERANL ILIAC
- D: LYMPH NODE, LEFT OBTURATOR
- E: LYMPH NODE, RIGHT PERI-AORTIC
- F: LYMPH NODE, LEFT PERI-AORTIC
- G: ABDOMINAL SCAR TISSUE

Gross Description

The specimens are received in seven containers of formalin, each labeled with the patient's name "[REDACTED]". The first container is labeled "uterus, tube and rt. ovary." It contains a previously opened uterus with attached right adnexa, and a fragment of left adnexa, measuring 2.5 x 1 x 0.4 cm, grossly consistent with atrophic ovary. No left fallopian tube is identified. The description and measurements match the intraoperative consultation. There are adhesions present at the anterior and posterior serosa. The ectocervix measures 1.5 x 2 cm, covered by hemorrhagic epithelium with an oval os. A necrotic area is present in the anterior cervix, measuring 0.5 x 0.3 cm. The endocervical canal measures 2 cm in length. The endometrium is filled with the polypoid tan-yellow mass, as described intraoperatively. The endometrium measures 2.5 cm in width and 4 cm in length. The maximum dimension of the mass is 6.5 cm. The mass is involving the lower uterine segment. Further sections show an endometrial thickness of 0.1 cm and a myometrium thickness of 1 to 2 cm. The tumor invades into the outer third of the myometrial wall. The right ovary measures 2 x 1 x 0.4 cm and sections of the ovary are unremarkable. The right fallopian tube measures 6 cm in length and 0.6 cm in diameter. One paratubal cyst, measuring 0.4 x 0.2 x 0.1 cm is present. The surface of the fallopian tube is unremarkable. Sections of the fallopian tube are unremarkable. Labeled A1 to A3 - strip of anterior cervix, endocervix, lower uterine segment and endomyometrium; A4, A5 - the other strip of anterior cervix, endocervix, lower uterine cervix and endomyometrium; A6 - sections of anterior endomyometrium with deepest invasion; A7 to A12 - two strips from posterior cervix, endocervix,

[page 3 of 4]
Patient Name: [REDACTED]

lower uterine segment and endomyometrium; A13 - the entirely submitted right ovary; A14 - sections of the right fallopian tube; A15 - section of the possible left ovary. Jar 2.

The second container is labeled "rt. pelvic lymph node." It contains a fragment of yellow adipose tissue bearing lymph nodes, measuring 4 x 4 x 0.5 cm. A few lymph nodes are dissected, ranging from 0.2 cm to 2.5 x 1 x 1 cm. The largest lymph node is firm and white, consistent with tumor involvement. Labeled B1 - section of the largest lymph node; B2, B3 - three lymph nodes, two bisected, half in B2 and half in B3, included in B3 is another small intact lymph node. Jar 1.

The third container is labeled "left external iliac lymph node." It contains multiple fragments of yellow adipose tissue, measuring 4.5 x 3.5 x 0.5 cm in aggregate. A few lymph nodes are dissected, ranging from 0.2 cm to 2 x 1 x 0.5 cm. Sections of the lymph nodes are unremarkable. Labeled C1, C2 - two bisected lymph nodes; C3 - one intact small lymph node. Jar 1.

The fourth container is labeled "lt. obturator lymph node." It contains two lymph nodes and a fragment of yellow fatty tissue, measuring 3 x 1 x 0.5 cm in aggregate. The two lymph nodes measure 0.4 x 0.4 x 0.2 cm and 3 x 0.8 x 0.3 cm. Sections of lymph nodes are unremarkable. One possible lymph node, measuring 0.3 cm in greatest dimension is also identified. D1 - larger lymph node, bisected; D2 - bisected smaller lymph node and the other intact possible lymph node. Jar 1.

The fifth container is labeled "rt. peri-aortic." It contains one fragment of yellow adipose tissue, bearing lymph nodes, measuring 7 x 1.2 x 0.4 cm. A few possible lymph nodes are identified, ranging from 1.2 to 1.5 cm in greatest dimension. Sections of the lymph nodes are unremarkable. Labeled E1 to E3 - dissected lymph nodes, one each, bisected. Jar 1.

The sixth container is labeled "lt. peri-aortic." It contains several fragments of yellow adipose tissue, measuring 2 x 1 x 0.4 cm in aggregate. Two possible lymph nodes are dissected, measuring 0.3 to 0.7 cm in maximum diameter. Sections of the lymph nodes are unremarkable. Labeled F1 - bisected lymph node; F2 - an intact lymph node. Jar 1.

The seventh container is labeled "abdominal scar tissue." It contains a linear fragment of white skin, measuring 14 cm in length, 0.6 cm in width to a depth of 0.3 cm. Two well healed linear scars, measuring 2 cm and 3 cm each are present on the surface. Sections of the fragments are unremarkable. Labeled G1 - random sections of the skin. Jar 1.

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT ENDOMETRIAL TUMORS

1. A NEOPLASM IS: Present
2. THE HISTOLOGIC DIAGNOSIS IS:
Malignant mixed Mullerian tumor, with heterologous stromal elements:
Malignant cartilage
3. THE MAXIMUM TUMOR SIZE IS 6.5 cm
4. THE LENGTH OF THE UTERINE CAVITY IS 4 cm
5. THE FIGO GRADE OF THE TUMOR IS:
Not applicable
6. THE NUCLEAR GRADE OF THE TUMOR IS:
NIII
7. INVASIVE TUMOR IS:
Present with invasion of the outer 1/3 of the myometrium
8. THE TUMOR INVADES TO A DEPTH OF 13 mm, with a MYOMETRIAL THICKNESS OF 18 mm
9. THE ENDOCERVIX IS:
Uninvolved by tumor

[page 4 of 4]
Patient Name: [REDACTED]

10. and 11. LYMPHOVASCULAR INVASION BY TUMOR IS:
Present but limited in scope
12. RESIDUAL NON-NEOPLASTIC ENDOMETRIAL TISSUE:
Shows atrophy
13. THE MYOMETRIUM:
Is involved by direct extension of the tumor
14. THE RIGHT OVARY:
Is free of tumor
15. THE LEFT OVARY:
Is free of tumor
16. THE RIGHT FALLOPIAN TUBE:
Is free of tumor
17. THE LEFT FALLOPIAN TUBE:
Is not evaluable
18. THE VAGINAL CUFF OF EXCISION IS:
Not evaluable
19. TUMOR INVASION OF ADJACENT STRUCTURES IS:
Not evaluable
20. METASTASIS TO THE OMENTUM AND PERITONEUM IS:
Not evaluable
21. "T" DATA-- THE TUMOR IS:

TNM Categories		FIGO Stages
T1c	IC	Tumor invades to more than one half of myometrium
N1	IIIC	Metastasis to pelvic and/or para-aortic lymph

nodes

22. THE REGIONAL LYMPH NODES:
Are involved by tumor in 2 of 20 nodes
Extranodal extension by tumor metastases is PRESENT
23. "N" DATA-- THE REGIONAL LYMPH NODES ARE:
N1 (Involved by metastases)
24. "M" DATA-- DISTANT METASTASES ARE:
MX (Not evaluable)
25. THE OVERALL PATHOLOGIC AJCC STAGE OF THE TUMOR IS:
Stage IIIC (T1/N1/MX)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Reviewer Initials	RB	Date Re-reviewed: 10/18/12

Source: NCI Genomic Data Commons file 6bd6a860-cd2d-41ce-bb4b-526aafa51422 (TCGA-N7-A4Y0.04D78BF5-445D-4F04-90ED-4AC0C8995915.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).